Somatic mutation profile of tumor specimen TCGA-XT-AASU-01A (aliquot TCGA-XT-AASU-01A-11D-A39R-32) from TCGA case TCGA-XT-AASU, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 60.3 years (22,021 days).
Specimen TCGA-XT-AASU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c667a380-8a1d-4775-9475-18baa63fcfbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XT-AASU-11A (Solid Tissue Normal), aliquot TCGA-XT-AASU-11A-13D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7843e728-f603-4ddf-9830-2deca3edb95d

The open-access MAF lists 41 somatic variants for this specimen: 33 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 5, Frame Shift Ins 2, 5'UTR 1, Frame Shift Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.8140G>A p.V2714I | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.079); catalogued as rs753223319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.8693C>G p.T2898S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.085); catalogued as rs1483236587, COSV100003574; called by muse, mutect2, varscan2
- DDR1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.133); catalogued as rs771047020, COSV61318772; called by muse, mutect2, varscan2
- FES | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188984508, COSV61002097; called by muse, mutect2, varscan2
- FREM1 | c.4583A>G p.D1528G | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as rs1029407111; called by muse, mutect2, varscan2
- GRIK3 | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66140161; called by muse, mutect2, varscan2
- NUDT6 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.709); catalogued as COSV99144711; called by muse, mutect2, varscan2
- RHOA | c.58T>G p.C20G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV69041533; called by muse, mutect2
- RIPK3 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV53475714; called by muse, mutect2, varscan2
- SIPA1L2 | c.4272G>A p.M1424I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs898639763; called by muse, mutect2
- ASCL4 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- BAP1 | c.1931dup p.N645Kfs*3 | Frame Shift Ins (INS) | VAF 21/125 reads (17%) | called by mutect2, pindel, varscan2
- CDC27 | c.2120T>G p.F707C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EPHA3 | c.2594G>T p.R865M | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR88 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GSG1 | c.304T>C p.S102P (on ENST00000651961 / NM_001080555.4; = p.S89P on NM_031289.5) | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- IRF2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.053); called by muse, mutect2
- MTFR1 | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NFKBIA | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NINJ1 | c.163_166del p.A55Cfs*2 | Frame Shift Del (DEL) | VAF 40/210 reads (19%) | called by mutect2, varscan2
- NPFFR2 | c.1055C>G p.A352G | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NUGGC | c.760A>G p.R254G | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- PAAF1 | c.590A>T p.D197V | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLR2A | c.4216A>G p.T1406A | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- PROZ | c.950G>T p.R317L | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR30 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RRNAD1 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SLC25A11 | c.632A>G p.D211G | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2
- TNFRSF10B | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TPMT | c.494G>C p.C165S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- USP10 | c.1886dup p.T630Hfs*39 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by mutect2, pindel
- VPS11 | c.1103T>C p.L368P (on ENST00000620429; = p.L912P on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); called by muse, mutect2
- ZC2HC1A | c.811A>G p.R271G | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- ACACB | c.165G>A p.G55= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as rs1565855979; called by muse, mutect2
- CSK | c.657C>T p.V219= | Silent (SNP) | VAF 53/250 reads (21%) | catalogued as rs146502156; called by muse, mutect2, varscan2
- PLXND1 | c.342C>T p.C114= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV60720076; called by muse, mutect2, varscan2
- SYT3 | c.171G>A p.S57= | Silent (SNP) | VAF 36/241 reads (15%) | catalogued as rs376592419; called by muse, mutect2, varscan2
- ZNF585A | c.624T>C p.H208= (on ENST00000292841 / NM_001288800.2; = p.H153= on NM_152655.3) | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs1293486797; called by muse, mutect2, varscan2
- ADAM8 | c.*5G>A | 3'UTR (SNP) | VAF 16/107 reads (15%) | catalogued as rs755015233; called by muse, mutect2, varscan2
- HDAC2 | c.-94C>T | 5'UTR (SNP) | VAF 13/63 reads (21%) | catalogued as rs749215157; called by muse, mutect2, varscan2
- ZNF160 | c.271+744C>A | Intron (SNP) | VAF 49/337 reads (15%) | called by muse, mutect2, varscan2
